CTSP case CTSP-ACY8 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f4eae82f-bd27-4fc1-b244-890608724ed0

Demographics
Sex at birth: female; Race: american indian or alaska native; Ethnicity: not hispanic or latino; Year of birth: 1929; Vital status: Dead; Days to death: 578 days (1.6 years); Year of death: 2007; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 76.5 years (27,945 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 578 days (1.6 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: Yes; International Prognostic Index (IPI): High-Intermediate Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 158 cm; BMI: 33.6.

Biospecimens (1 sample)
- Sample DLBCL11286-sample: Sample type: Tumor; Tissue type: Tumor.
